CCDI case PBCNJH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Meningiomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/8b17cb95-9398-4683-820b-4c6377bd4b32

Demographics
Sex at birth: female; Race: asian.

Diagnoses (1)
1. Meningioma, NOS: ICD-O-3 morphology code: 9530/0; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.0 years (5,860 days).

Biospecimens (3 samples)
- Sample 0DW72N: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DW72U: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DW746: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
